Somatic mutation profile of tumor specimen TCGA-CC-5263-01A (aliquot TCGA-CC-5263-01A-01D-A12Z-10) from TCGA case TCGA-CC-5263, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 35.2 years (12,863 days).
Specimen TCGA-CC-5263-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c92f478e-03ad-46b7-afa5-ea05ca6ba2c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-5263-10B (Blood Derived Normal), aliquot TCGA-CC-5263-10B-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80dad965-0d30-4ca6-911f-a2b20eaef06d

The open-access MAF lists 130 somatic variants for this specimen: 98 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 30, Nonsense Mutation 12, Frame Shift Del 4, Splice Site 2, Intron 1, Translation Start Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.831T>A p.C277* | Nonsense Mutation (SNP) | VAF 43/61 reads (70%) | hotspot (GDC flag); catalogued as rs1057523347, CM065496, COSV52676368, COSV52783531, COSV53164903; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.2794A>T p.K932* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV54029451; called by muse, mutect2, varscan2
- ABHD8 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV53112880; called by muse, mutect2
- ADGRV1 | c.206C>A p.S69* | Nonsense Mutation (SNP) | VAF 60/103 reads (58%) | catalogued as COSV67985171; called by muse, mutect2, varscan2
- AOAH | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.138); catalogued as COSV51741460; called by muse, mutect2
- ARAF | c.1245G>T p.Q415H | Missense Mutation (SNP) | VAF 81/102 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51692732; called by muse, mutect2, varscan2
- ATP2A1 | c.119-2A>G p.X40_splice | Splice Site (SNP) | VAF 82/214 reads (38%) | catalogued as rs201535825, COSV59463033; called by muse, mutect2, varscan2
- B4GALNT3 | c.2858G>A p.W953* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV56752422, COSV56758869; called by muse, mutect2, varscan2
- BCL9 | c.2346A>T p.R782S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.059); catalogued as COSV52344297; called by muse, mutect2, varscan2
- BTN2A2 | c.952+1G>A p.X318_splice | Splice Site (SNP) | VAF 187/655 reads (29%) | catalogued as rs200463511, COSV61856950, COSV61857844; called by muse, mutect2, varscan2
- CD19 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 204/538 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.442); catalogued as COSV61188550; called by muse, mutect2, varscan2
- CEP135 | c.1568A>T p.Q523L | Missense Mutation (SNP) | VAF 162/411 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57260044; called by muse, mutect2, varscan2
- CEP76 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50866623; called by muse, mutect2, varscan2
- CFAP61 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55629311; called by mutect2, varscan2
- CFAP65 | c.1658T>C p.L553P | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58560995; called by muse, mutect2
- CHD8 | c.2329C>T p.R777W (on ENST00000646647 / NM_001170629.2; = p.R498W on NM_020920.4) | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs747838726, COSV67870544; called by muse, mutect2, varscan2
- CITED2 | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 131/258 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV100863087; called by muse, mutect2, varscan2
- CLCN4 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 136/186 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV101073585; called by muse, mutect2, varscan2
- COL22A1 | c.2203G>T p.G735* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV57336879; called by muse, mutect2, varscan2
- CRLF3 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV60835864; called by muse, mutect2, varscan2
- CYP4A22 | c.863A>G p.H288R | Missense Mutation (SNP) | VAF 158/402 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV53740127; called by muse, mutect2, varscan2
- DOK1 | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs751060609, COSV51207587; called by muse, varscan2
- EGFLAM | c.1982T>A p.F661Y | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59302181; called by muse, mutect2, varscan2
- EIF4G3 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 137/364 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as COSV51682125; called by muse, mutect2, varscan2
- ELMO2 | c.937A>G p.R313G | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV51682979; called by muse, mutect2, varscan2
- ERCC6 | c.1012A>T p.R338W | Missense Mutation (SNP) | VAF 334/898 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV63390071; called by muse, varscan2
- EVA1B | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.556); catalogued as rs748202520, COSV54634201, COSV54634877, COSV99584108; called by muse, varscan2
- FGF20 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV51661350; called by muse, mutect2, varscan2
- FILIP1 | c.1330A>T p.K444* | Nonsense Mutation (SNP) | VAF 310/620 reads (50%) | catalogued as COSV52729669; called by muse, mutect2, varscan2
- FNIP2 | c.2285A>T p.Q762L | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1414145142, COSV52439838; called by muse, mutect2, varscan2
- FPGT | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774351798, COSV63833970, COSV63839834; called by muse, mutect2, varscan2
- GRIA2 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 209/555 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642401; called by muse, mutect2, varscan2
- GRIA2 | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 207/548 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642404; called by muse, mutect2, varscan2
- HOXD4 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV60459638, COSV60460237; called by muse, mutect2, varscan2
- IGF2R | c.1099G>T p.G367* | Nonsense Mutation (SNP) | VAF 54/183 reads (30%) | catalogued as COSV63629156; called by muse, mutect2, varscan2
- KHSRP | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs764189159, COSV67919702; called by muse, mutect2, varscan2
- KIAA1109 | c.13885G>A p.V4629I | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1054131463, COSV52672970; called by muse, mutect2, varscan2
- KIF19 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63429428; called by muse, mutect2, varscan2
- KL | c.2839A>G p.I947V | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as COSV66308792; called by muse, mutect2, varscan2
- KRT28 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 193/705 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60685132; called by muse, mutect2, varscan2
- LPO | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 198/371 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99228178; called by muse, mutect2, varscan2
- LRP8 | c.2752C>A p.P918T | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.026); catalogued as COSV100035891; called by muse, mutect2, varscan2
- MAB21L1 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as COSV100075651; called by muse, mutect2, varscan2
- MASTL | c.1903A>T p.M635L | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV60909947, COSV60910779; called by muse, mutect2, varscan2
- MCM7 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57996420; called by muse, varscan2
- MPP2 | c.863A>C p.Q288P (on ENST00000461854 / NM_001278372.2; = p.Q264P on NM_005374.5) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV52235839; called by muse, mutect2, varscan2
- MYH7 | c.251T>C p.F84S | Missense Mutation (SNP) | VAF 105/270 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV62519225; called by muse, mutect2, varscan2
- MYLK3 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV67364265; called by muse, varscan2
- NALCN | c.4547G>A p.C1516Y | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51935691; called by muse, mutect2, varscan2
- NF2 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV58523885; called by muse, mutect2, varscan2
- NOX3 | c.1581C>A p.S527R | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.9); catalogued as COSV50152558; called by muse, mutect2, varscan2
- NPBWR2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.068); catalogued as rs748131572, COSV63900129; called by muse, mutect2, varscan2
- NR4A2 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV59893850; called by muse, mutect2, varscan2
- NUMA1 | c.4718A>C p.K1573T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV61185603; called by muse, mutect2
- OR4F15 | c.683A>T p.H228L | Missense Mutation (SNP) | VAF 242/931 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV59969091; called by muse, mutect2, varscan2
- OR5M10 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 187/483 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV73242319; called by muse, mutect2, varscan2
- OR6C75 | c.627G>T p.L209F | Missense Mutation (SNP) | VAF 159/431 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV58552224; called by muse, mutect2, varscan2
- PDE10A | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63096631; called by muse, mutect2
- PDXDC1 | c.1651A>T p.K551* | Nonsense Mutation (SNP) | VAF 49/129 reads (38%) | catalogued as COSV55074314; called by muse, mutect2, varscan2
- PGLYRP4 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62835278; called by muse, mutect2, varscan2
- PPARD | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/107 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.38); catalogued as COSV61099713; called by muse, mutect2, varscan2
- PRB3 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 201/495 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV99685400; called by muse, varscan2
- PTGER3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.943); catalogued as COSV60691851; called by muse, mutect2, varscan2
- PTPA | c.1034A>G p.K345R (on ENST00000337738 / NM_178001.2; = p.K310R on NM_021131.5) | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV61234933; called by muse, varscan2
- PTPA | c.1037T>C p.F346S (on ENST00000337738 / NM_178001.2; = p.F311S on NM_021131.5) | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61234937; called by muse, varscan2
- RALBP1 | c.1951A>T p.K651* | Nonsense Mutation (SNP) | VAF 45/131 reads (34%) | catalogued as COSV50035389; called by muse, mutect2, varscan2
- RCOR1 | c.773A>G p.E258G | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV51768191; called by muse, mutect2, varscan2
- SASH1 | c.3434T>A p.M1145K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV66561677; called by muse, mutect2, varscan2
- SCCPDH | c.928A>T p.I310L | Missense Mutation (SNP) | VAF 310/880 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV63618526; called by muse, mutect2, varscan2
- SEPTIN2 | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs533422343, COSV63472117; called by muse, mutect2, varscan2
- SIGLEC1 | c.5123T>A p.L1708Q | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV52463806; called by muse, mutect2, varscan2
- SLC1A3 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs763798684, COSV54316593; called by muse, mutect2, varscan2
- SLC22A18 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV56540071; called by muse, mutect2, varscan2
- SMG8 | c.815A>G p.N272S | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.096); catalogued as rs548055635, COSV56285219; called by muse, varscan2
- SNRPB2 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 214/584 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99855792; called by muse, varscan2
- ST6GALNAC1 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 190/620 reads (31%) | PolyPhen benign (0); catalogued as rs771043163, COSV50074454; called by muse, mutect2, varscan2
- SYCP2 | c.3737del p.R1246Kfs*6 | Frame Shift Del (DEL) | VAF 65/205 reads (32%) | catalogued as COSV62767880; called by mutect2, pindel, varscan2
- SYT4 | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54900414; called by muse, mutect2, varscan2
- SYT6 | c.1161C>A p.N387K (on ENST00000610222 / NM_001366225.1; = p.N302K on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65773758; called by muse, mutect2, varscan2
- TBX19 | c.571T>C p.F191L | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV63197507; called by muse, mutect2, varscan2
- TDRD5 | c.1130A>T p.Q377L | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54242695; called by muse, mutect2, varscan2
- TET3 | c.4028A>T p.Q1343L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV69642594; called by muse, mutect2, varscan2
- TGM1 | c.1294G>T p.V432F | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52863114; called by muse, mutect2, varscan2
- TGM1 | c.446T>C p.M149T | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1267506182, COSV52863123; called by muse, mutect2, varscan2
- TMEM170A | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV62923118; called by muse, mutect2, varscan2
- TMEM59L | c.948G>A p.W316* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53242242; called by muse, mutect2, varscan2
- TPST1 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV59177031; called by muse, mutect2, varscan2
- TTC21A | c.2233G>T p.E745* | Nonsense Mutation (SNP) | VAF 42/63 reads (67%) | catalogued as COSV57185049; called by muse, mutect2, varscan2
- TTN | c.83560C>T p.L27854F (on ENST00000591111; = p.L20430F on NM_003319.4) | Missense Mutation (SNP) | VAF 74/183 reads (40%) | PolyPhen benign (0.001); catalogued as COSV60061340; called by muse, mutect2, varscan2
- UBE2M | c.526A>C p.T176P | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as COSV99447856; called by muse, mutect2, varscan2
- UNC79 | c.4496A>G p.Q1499R (on ENST00000393151 / NM_001346218.2; = p.Q1322R on NM_020818.5) | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV56387898; called by muse, mutect2, varscan2
- ZC3H7B | c.1299C>T p.G433= | Splice Region (SNP) | VAF 35/104 reads (34%) | catalogued as rs771064872, COSV60961870; called by muse, mutect2, varscan2
- ZNF264 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 75/180 reads (42%) | catalogued as COSV54041843; called by muse, mutect2, varscan2
- ZNF681 | c.584T>A p.V195E | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV68074292; called by muse, mutect2, varscan2
- CLPTM1L | c.97A>C p.T33P | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by mutect2, varscan2
- MYO5A | c.3887del p.L1296Wfs*7 | Frame Shift Del (DEL) | VAF 90/269 reads (33%) | called by mutect2, pindel, varscan2
- RETREG3 | c.1343_1350del p.E448Gfs*14 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- ZNF141 | c.1158_1171del p.K387Rfs*7 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | called by mutect2, pindel, varscan2
- ABCC5 | c.3024A>T p.A1008= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV55590139; called by muse, mutect2, varscan2
- CALN1 | c.123C>A p.I41= (on ENST00000329008 / NM_001017440.3; = p.I83= on NM_031468.4) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV61132655; called by muse, mutect2, varscan2
- CITED2 | c.408G>A p.P136= | Silent (SNP) | VAF 128/256 reads (50%) | catalogued as rs1008223876, COSV100863086, COSV100863131; called by muse, mutect2, varscan2
- CLTC | c.3264T>C p.H1088= | Silent (SNP) | VAF 88/168 reads (52%) | catalogued as COSV52247748; called by muse, mutect2, varscan2
- FASN | c.6531C>T p.R2177= | Silent (SNP) | VAF 64/104 reads (62%) | catalogued as rs1160132362, COSV60754755; called by muse, mutect2, varscan2
- ITPK1 | c.144G>A p.E48= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV50895394; called by muse, mutect2, varscan2
- KIAA2026 | c.3000G>A p.Q1000= | Silent (SNP) | VAF 108/338 reads (32%) | catalogued as rs1401584987, COSV67354895; called by muse, mutect2, varscan2
- KIF26B | c.2343G>A p.A781= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs201075952, COSV63641606; called by muse, mutect2, varscan2
- KRT78 | c.987C>T p.I329= | Silent (SNP) | VAF 138/369 reads (37%) | catalogued as COSV58851325; called by muse, mutect2, varscan2
- LAT | c.723C>A p.S241= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as COSV62795684; called by muse, mutect2, varscan2
- LCP2 | c.426C>T p.D142= | Silent (SNP) | VAF 114/313 reads (36%) | catalogued as rs561432915, COSV50450599; called by muse, mutect2, varscan2
- MAB21L1 | c.84C>A p.A28= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as COSV100075650; called by muse, mutect2, varscan2
- MLPH | c.1281G>A p.A427= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs202229121, COSV52820316; called by muse, mutect2, varscan2
- MPPE1 | c.438A>T p.P146= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as COSV57882533; called by muse, mutect2, varscan2
- MUC16 | c.35832C>G p.T11944= | Silent (SNP) | VAF 137/419 reads (33%) | catalogued as COSV67465864; called by muse, mutect2, varscan2
- MYO3B | c.1366T>C p.L456= | Silent (SNP) | VAF 114/320 reads (36%) | catalogued as rs1300424440, COSV58703205; called by mutect2, varscan2
- NUP210L | c.2730T>C p.Y910= | Silent (SNP) | VAF 104/292 reads (36%) | catalogued as COSV55147524; called by muse, mutect2, varscan2
- OPHN1 | c.1998A>T p.P666= | Silent (SNP) | VAF 160/204 reads (78%) | catalogued as COSV62782395; called by muse, mutect2, varscan2
- OR4M1 | c.941G>A p.*314= | Silent (SNP) | VAF 90/503 reads (18%) | catalogued as COSV60061342; called by muse, mutect2, varscan2
- PPP1R12C | c.1236A>G p.E412= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1224863989, COSV54737359; called by muse, mutect2, varscan2
- PTPN5 | c.1416G>A p.L472= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100078924, COSV60037379; called by muse, mutect2, varscan2
- RNF182 | c.45T>C p.S15= | Silent (SNP) | VAF 84/192 reads (44%) | catalogued as COSV70369225; called by muse, mutect2
- RXFP3 | c.972C>A p.V324= | Silent (SNP) | VAF 91/151 reads (60%) | catalogued as rs772154868, COSV57505560; called by muse, mutect2, varscan2
- SEMA3C | c.891C>A p.G297= | Silent (SNP) | VAF 56/158 reads (35%) | catalogued as COSV54846544; called by muse, mutect2, varscan2
- SLIT3 | c.2859T>C p.T953= | Silent (SNP) | VAF 58/170 reads (34%) | catalogued as rs1203859802, COSV60608247; called by muse, mutect2
- ST6GALNAC6 | c.99A>G p.R33= | Silent (SNP) | VAF 110/382 reads (29%) | catalogued as COSV99398274; called by muse, mutect2, varscan2
- STXBP3 | c.1389G>T p.R463= | Silent (SNP) | VAF 208/531 reads (39%) | catalogued as COSV64182206; called by muse, varscan2
- TNFRSF19 | c.1215C>A p.V405= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV50313580; called by muse, mutect2, varscan2
- YWHAG | c.114G>C p.S38= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV56901071; called by muse, mutect2, varscan2
- ZNF230 | c.372C>G p.S124= | Silent (SNP) | VAF 92/129 reads (71%) | catalogued as COSV71273420; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288130T>A | Intron (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- GATA3 | chr10:8051162 G>T | 5'Flank (SNP) | VAF 90/192 reads (47%) | catalogued as rs563461889; called by muse, mutect2, varscan2
